Somatic mutation profile of tumor specimen MP2PRT-PAVEPK-TMP1-A (aliquot MP2PRT-PAVEPK-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVEPK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,293 days).
Specimen MP2PRT-PAVEPK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 107293bf-12da-43fb-b233-06e0b83c7921.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVEPK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVEPK-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac689d88-03e4-44d1-b6fd-ce3cf720cd74

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Nonsense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG10 | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.356); catalogued as rs1418195338; called by muse, mutect2
- DIP2A | c.4102G>A p.V1368M | Missense Mutation (SNP) | VAF 85/297 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769053637, COSV100596556; called by muse, mutect2, varscan2
- DPEP1 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 117/365 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs375079646; called by muse, mutect2, varscan2
- FN1 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 14/467 reads (3%) | catalogued as COSV60548120; called by muse, mutect2
- FSTL5 | c.2074G>A p.D692N | Missense Mutation (SNP) | VAF 16/440 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV60196138; called by muse, mutect2
- HIVEP3 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 25/399 reads (6%) | catalogued as COSV56009059; called by muse, mutect2
- PCDHGB2 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 14/434 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV53960191; called by muse, mutect2
- MROH9 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 282/471 reads (60%) | called by muse, mutect2, varscan2
- PHIP | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAS2R1 | c.550T>C p.S184P | Missense Mutation (SNP) | VAF 11/292 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- FBXW11 | c.1344C>T p.C448= | Silent (SNP) | VAF 37/250 reads (15%) | called by muse, mutect2, varscan2
